Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2U, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2U-01A (Primary Tumor).

Female

Surgery Date:

DIAGNOSIS:

A. Liver, segments IVb, v, VI, VII and VIII and gallbladder, partial hepatectomy and cholecystectomy: Grade 3 (of 4) cholangiocarcinoma, forming a 10.0 x 8.3 x 6.9 cm mass. Angiolymphatic invasion is absent. The cystic duct is negative for tumor. The closest surgical resection margin is 0.2 cm. Embolization coils are identified. A single (1) cystic duct lymph node is negative for tumor. Minimal chronic cholecystitis is identified. The hepatic parenchyma is unremarkable. [AJCCpT1N0MX]

B. Lymph node, retrocholedochal, biopsy: A single (1) lymph node is negative for tumor.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

JW 3/8/14

Source: NCI Genomic Data Commons file 913010a5-b956-412e-bf80-efd18b655a6f (TCGA-W5-AA2U.205BDA9B-D391-4075-B1A6-32CBF06B06EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).